Gene-level copy-number profile of tumor specimen ALCH-ADJ3-TTP1-A from ALCHEMIST case ALCH-ADJ3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.4 years (23,873 days).
Specimen ALCH-ADJ3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2063b27a-a79e-4df9-ba0b-1b4280eddb02.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADJ3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/fd47709a-146a-4b5a-99d8-c7ebd8bea4ba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 234; copy number 1: 6,602; copy number 2: 50,032; copy number 3: 2,022; copy number 4: 16.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:240,886,048–240,896,889, 1 gene: MAB21L4.
- chr7:1,074,450–1,082,178, 2 genes (within-gene range 0–2): AC091729.1, AC091729.2.
- chr7:151,409,161–151,413,354, 1 gene (within-gene range 0–2): WDR86-AS1.
- chr9:135,693,407–135,704,498, 1 gene (within-gene range 0–1): SOHLH1.
- chr11:69,641,156–69,654,474, 1 gene (within-gene range 0–2): CCND1.
- chr16:90,173,217–90,222,851, 1 gene (within-gene range 0–1): LINC02193.
- chr19:4,007,736–4,066,899, 3 genes: PIAS4, ZBTB7A, AC016586.1.
- chr20:33,657,087–33,675,380, 5 genes: NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1.
- chr21:44,328,944–44,330,221, 1 gene (within-gene range 0–2): AP001062.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,978. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
